Gene-level copy-number profile of tumor specimen TCGA-FZ-5920-01A from TCGA case TCGA-FZ-5920, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.8 years (19,287 days).
Specimen TCGA-FZ-5920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.9200cba6-9843-465b-b6aa-dc3936622de5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FZ-5920-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/236ffb41-939f-435a-92e0-d0420f624b48

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 693; copy number 2: 13,732; copy number 3: 12,655; copy number 4: 25,206; copy number 5: 5,830; copy number 6: 154; copy number 7: 245; copy number 8: 485; copy number 9: 315; copy number 10: 110; copy number 11: 56; copy number 12: 32; copy number 13: 29; copy number 14: 61; copy number 15: 3; copy number 16: 141; copy number 17: 13; copy number 23: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FZ-5920-01A-11D-1608-01): tumor purity 0.25, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 801 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:115,976,513–120,127,074, 92 genes, copy number 9–23 (within-gene range 2–23) (broad region; genes not listed).
- chr3:83,924,157–86,074,429, 12 genes, copy number 10–15 (within-gene range 4–15): AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2.
- chr3:168,666,559–171,460,408, 58 genes, copy number 9 (within-gene range 3–9): RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569.
- chr3:178,419,123–178,843,300, 1 gene, copy number 10 (within-gene range 3–10): AC117457.1.
- chr3:178,526,505–179,394,936, 11 genes, copy number 10 (within-gene range 3–10): KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1.
- chr7:29,514,224–32,428,131, 56 genes, copy number 9–16 (within-gene range 4–16): AC007255.1, GTF3C6P3, PRR15, ZNRF2P2, TMSB4XP3, DPY19L2P3, MIR550A3, WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3, GARS1, CRHR2, INMT, AC006022.1, INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR, ADCYAP1R1, AC006466.1, AC006398.1, AC006380.1, NEUROD6, AC005090.1, ITPRID1, PPP1R17, PDE1C, SNX2P2.
- chr7:47,252,139–52,192,913, 55 genes, copy number 11–13: AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1.
- chr11:33,740,939–40,112,599, 75 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr11:40,351,564–40,513,269, 2 genes, copy number 9: Y_RNA, AC090720.1.
- chr11:42,183,292–44,310,139, 37 genes, copy number 9: LINC02740, AC109810.1, AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1, AC087521.3, C11orf96, AC087521.1, ACCSL, ACCS, AC134775.1, EXT2, ALX4.
- chr11:45,929,319–47,594,411, 61 genes, copy number 14 (within-gene range 2–14) (broad region; genes not listed).
- chr12:30,086,342–31,993,107, 60 genes, copy number 9: AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1.
- chr12:38,201,566–40,211,419, 25 genes, copy number 9 (within-gene range 5–9): TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471.
- chr12:64,759,484–74,402,600, 166 genes, copy number 12–17 (within-gene range 2–17) (broad region; genes not listed).
- chr18:43,115,747–47,282,939, 63 genes, copy number 10 (broad region; genes not listed).
- chr18:47,380,496–47,380,565, 1 gene, copy number 10: MIR4527.
- chr18:69,212,277–71,237,158, 26 genes, copy number 10–17: AC090337.1, AC090337.2, AC026585.1, DOK6, AC119868.1, AC119868.2, AC068254.2, AC068254.1, CD226, RTTN, AC021701.1, SOCS6, LINC01909, LIVAR, LINC01910, LARP7P3, RPS2P6, AC091305.1, AC091646.1, RN7SL795P, GTSCR1, AC090415.2, AC090415.1, AC091691.3, AC091691.2, AC091691.1.

Autosomal genes at a single copy (total copy number 1): 693. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
